Somatic mutation profile of tumor specimen TCGA-22-1016-01A (aliquot TCGA-22-1016-01A-01D-1521-08) from TCGA case TCGA-22-1016, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-22-1016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec9e87d7-d5a6-4f8e-b093-9705960f39ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1016-11A (Solid Tissue Normal), aliquot TCGA-22-1016-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b75b3d88-f68b-4a98-ada3-b7104421d207

The open-access MAF lists 384 somatic variants for this specimen: 293 protein-altering or splice-affecting, 84 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 84, Nonsense Mutation 27, Splice Site 10, Frame Shift Del 9, Intron 3, Splice Region 3, RNA 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3202G>T p.D1068Y (on ENST00000404938 / NM_001163941.2; = p.D623Y on NM_178559.6) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51716059; called by muse, mutect2, varscan2
- ABCG8 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV55395197; called by muse, mutect2, varscan2
- ABLIM3 | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58646569; called by muse, mutect2, varscan2
- ACCS | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1362031914, COSV55459505; called by muse, mutect2, varscan2
- ACE2 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV53026505; called by muse, mutect2, varscan2
- ACSM4 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV68068704; called by muse, mutect2, varscan2
- ADAM12 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV64111056; called by muse, mutect2, varscan2
- ADAMTS17 | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as COSV51488035; called by muse, mutect2, varscan2
- ADAMTS3 | c.1726C>G p.R576G | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54397513, COSV99710659; called by muse, mutect2, varscan2
- ADGRL4 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV66060786, COSV66063775; called by muse, varscan2
- ALDH1L1 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV56417056; called by muse, mutect2, varscan2
- AMPD1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV62417484; called by muse, mutect2, varscan2
- ANK2 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52176963; called by muse, mutect2, varscan2
- ANK2 | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52176977; called by muse, mutect2, varscan2
- ANKRD26 | c.3548A>G p.E1183G | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV65776972; called by muse, mutect2, varscan2
- ANKRD34B | c.1287G>T p.R429S | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV58614281; called by muse, mutect2, varscan2
- ANKRD40 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53334331; called by muse, mutect2, varscan2
- ANKRD52 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV57286103; called by muse, mutect2, varscan2
- ATG16L2 | c.1605C>G p.N535K | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV58362471; called by muse, mutect2, varscan2
- ATP12A | c.2035G>T p.V679L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54519902; called by muse, mutect2, varscan2
- ATP13A4 | c.153C>G p.Y51* | Nonsense Mutation (SNP) | VAF 97/230 reads (42%) | catalogued as COSV55072622; called by muse, mutect2, varscan2
- ATP8B2 | c.1858G>T p.E620* (on ENST00000672630; = p.E587* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 43/136 reads (32%) | catalogued as COSV59247585; called by muse, mutect2, varscan2
- BAIAP3 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs372927860, COSV50104621; called by muse, mutect2, varscan2
- BBS1 | c.723+1G>A p.X241_splice | Splice Site (SNP) | VAF 13/85 reads (15%) | catalogued as COSV59150626; called by muse, mutect2, varscan2
- BCAR3 | c.1682G>A p.C561Y | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53077395; called by muse, mutect2, varscan2
- BCHE | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs751164424, COSV52253716; called by muse, mutect2, varscan2
- BCKDHB | c.197-2A>T p.X66_splice | Splice Site (SNP) | VAF 40/289 reads (14%) | catalogued as CS159343, COSV57516395; called by muse, mutect2
- BCL7A | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55850166; called by muse, mutect2, varscan2
- BLM | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV61925882, COSV61927390; called by muse, mutect2
- BSDC1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV61982127; called by mutect2, varscan2
- C14orf28 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 53/335 reads (16%) | catalogued as rs773957213, COSV57333887; called by muse, mutect2, varscan2
- CACNA1F | c.5099G>A p.R1700K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV59905858; called by muse, mutect2, varscan2
- CAPN6 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60696244; called by muse, varscan2
- CCDC110 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as COSV56872519; called by muse, mutect2, varscan2
- CD101 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56719743; called by muse, mutect2, varscan2
- CDC6 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1415436932, COSV52931070, COSV52931234; called by muse, mutect2, varscan2
- CDH1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV55735462; called by muse, mutect2, varscan2
- CHD5 | c.5501G>A p.C1834Y | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52420835; called by muse, mutect2
- CHD7 | c.6712G>T p.E2238* | Nonsense Mutation (SNP) | VAF 74/131 reads (56%) | catalogued as COSV71113053; called by muse, mutect2, varscan2
- CIITA | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV60854647, COSV60859566; called by muse, mutect2, varscan2
- CLDN18 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV59303940; called by muse, mutect2, varscan2
- CLDN25 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs768889315, COSV71620462; called by muse, mutect2, varscan2
- CLK2 | c.16A>T p.R6W | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62877841; called by muse, mutect2, varscan2
- CMYA5 | c.11162C>A p.T3721K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1295510453, COSV71408047; called by muse, mutect2, varscan2
- CNKSR2 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV54262069; called by muse, mutect2, varscan2
- CNOT3 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV55366154; called by muse, mutect2, varscan2
- CNTNAP5 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70499851; called by muse, mutect2, varscan2
- COL20A1 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.262); catalogued as COSV58923054; called by muse, mutect2, varscan2
- COL2A1 | c.3190G>T p.V1064L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61532550; called by muse, mutect2, varscan2
- COL6A6 | c.4319G>A p.G1440E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032130; called by muse, mutect2, varscan2
- COPS5 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV63474705; called by muse, mutect2
- CPA3 | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs1296218522, COSV56046409; called by muse, mutect2, varscan2
- CSF3R | c.185T>A p.L62Q | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV58969530; called by muse, mutect2, varscan2
- CSMD1 | c.1002C>A p.N334K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); catalogued as COSV68233237; called by muse, mutect2, varscan2
- CSMD3 | c.9495A>T p.L3165F (on ENST00000297405 / NM_001363185.1; = p.L2996F on NM_052900.3) | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52257692; called by muse, mutect2, varscan2
- CTNNA2 | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1262697787, COSV63586644; called by muse, mutect2, varscan2
- CTNND1 | c.2876A>T p.Q959L (on ENST00000399050 / NM_001085458.2; = p.Q932L on NM_001331.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV62385034; called by muse, mutect2, varscan2
- CYP11B1 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV52829105; called by muse, mutect2
- CYP1A1 | c.1322A>T p.K441M | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65697853; called by muse, mutect2, varscan2
- CYP2C19 | c.1095C>A p.S365R | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV64908667; called by muse, mutect2, varscan2
- CYP2C19 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as rs1345358265, COSV64908671; called by muse, mutect2, varscan2
- DAAM2 | c.1830G>T p.W610C | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51372059; called by muse, mutect2, varscan2
- DCLK2 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 101/352 reads (29%) | catalogued as COSV56208722, COSV56209600; called by muse, mutect2, varscan2
- DDIAS | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV61272789; called by muse, mutect2, varscan2
- DDX23 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57283543, COSV57285220; called by muse, mutect2, varscan2
- DEFB136 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.378); catalogued as COSV66363992; called by muse, mutect2, varscan2
- DES | c.1231G>C p.G411R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV64660766; called by muse, mutect2, varscan2
- DNAH7 | c.4761C>G p.F1587L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV56770098, COSV56776303; called by muse, mutect2, varscan2
- DNAH7 | c.4548G>T p.K1516N | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56776331; called by muse, mutect2, varscan2
- DSCAML1 | c.5242G>T p.E1748* (on ENST00000321322; = p.E1688* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 33/128 reads (26%) | catalogued as COSV58397762; called by muse, mutect2, varscan2
- DTX2 | c.1702A>G p.S568G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV56863466; called by muse, mutect2
- DUSP6 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54379249; called by muse, mutect2, varscan2
- DYNC1H1 | c.10949A>T p.N3650I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64139862; called by muse, mutect2, varscan2
- ENAM | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1560405648, COSV68536633; called by muse, mutect2, varscan2
- ENPP1 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.531); catalogued as COSV62934629; called by muse, mutect2, varscan2
- ERCC3 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV53428702; called by muse, mutect2, varscan2
- F5 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63126247; called by muse, mutect2
- FAM24A | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.833); catalogued as COSV64406080; called by muse, mutect2, varscan2
- FCRL1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV63826421; called by muse, mutect2, varscan2
- FCRL3 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV63843642; called by muse, mutect2, varscan2
- FFAR3 | c.726C>A p.N242K | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59909420; called by muse, mutect2, varscan2
- FHL5 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs201297556, COSV58739274; called by muse, mutect2, varscan2
- FKBP10 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs1555616658, COSV58638148; called by muse, mutect2, varscan2
- FMN2 | c.4690G>T p.D1564Y | Missense Mutation (SNP) | VAF 124/541 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60443070; called by muse, mutect2, varscan2
- GAK | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 22/143 reads (15%) | catalogued as COSV58507371; called by muse, mutect2, varscan2
- GBGT1 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV64410188, COSV64410484; called by muse, mutect2, varscan2
- GIMAP7 | c.864G>C p.W288C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV57960059; called by muse, mutect2, varscan2
- GIMAP8 | c.877T>C p.W293R | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230777, COSV56232957; called by muse, mutect2, varscan2
- GJA8 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV53789718; called by muse, mutect2, varscan2
- GJA8 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.395); catalogued as COSV53789729; called by muse, mutect2, varscan2
- GP5 | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV55467588; called by muse, mutect2, varscan2
- GPC5 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV65605013, COSV65615616; called by muse, mutect2, varscan2
- GPR149 | c.987C>A p.H329Q | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67668794; called by muse, mutect2
- GRIA1 | c.2596G>T p.G866* | Nonsense Mutation (SNP) | VAF 50/115 reads (43%) | catalogued as COSV53615081; called by muse, mutect2, varscan2
- GRM4 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65216693; called by muse, mutect2
- HBS1L | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV59022100; called by muse, mutect2, varscan2
- HCLS1 | c.1323A>T p.G441= | Splice Region (SNP) | VAF 40/274 reads (15%) | catalogued as COSV57526108; called by muse, mutect2, varscan2
- HEPHL1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1246577650, COSV59894427; called by muse, mutect2, varscan2
- HHLA2 | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV63318856; called by muse, mutect2
- HHLA2 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63318874; called by muse, mutect2, varscan2
- HOXD3 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV50883147; called by muse, mutect2, varscan2
- IBSP | c.735A>C p.R245S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV56896602; called by muse, mutect2, varscan2
- IL1R2 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV60206495, COSV60208586; called by muse, mutect2, varscan2
- INSYN2A | c.140T>A p.V47E | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54748566, COSV54750854; called by muse, mutect2, varscan2
- IRS1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59338449; called by muse, mutect2, varscan2
- ISLR2 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV62302920; called by muse, mutect2
- ISM2 | c.1114+1G>C p.X372_splice (on ENST00000342219 / NM_199296.3; = p.X256_splice on NM_182509.4) | Splice Site (SNP) | VAF 27/109 reads (25%) | catalogued as COSV53636158; called by muse, mutect2, varscan2
- ITPR2 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV67273449; called by muse, mutect2, varscan2
- JPH2 | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV65904765; called by muse, mutect2, varscan2
- KCND2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV58594024, COSV58604673; called by muse, mutect2, varscan2
- KCNH1 | c.2065C>A p.H689N (on ENST00000271751 / NM_172362.3; = p.H662N on NM_002238.4) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55093299; called by muse, mutect2, varscan2
- KCNIP3 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54671244; called by muse, mutect2, varscan2
- KIF25 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 57/515 reads (11%) | catalogued as COSV63028228; called by muse, varscan2
- KLHL32 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV65113589; called by muse, mutect2, varscan2
- KLHL4 | c.591-1G>T p.X197_splice | Splice Site (SNP) | VAF 30/72 reads (42%) | catalogued as COSV64145678; called by muse, mutect2, varscan2
- KLHL9 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62922213; called by muse, mutect2, varscan2
- KMT2D | c.9997C>T p.Q3333* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56458908; called by muse, mutect2, varscan2
- KNTC1 | c.5128T>C p.F1710L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs1328858161, COSV61082404; called by muse, varscan2
- KRBA1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55443063; called by muse, mutect2, varscan2
- KRTAP1-3 | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV60336725; called by muse, mutect2, varscan2
- LCE3E | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); catalogued as rs748179368, COSV64232054; called by muse, mutect2, varscan2
- LITAF | c.214A>T p.N72Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV59656551; called by muse, mutect2
- LMF1 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV51900247; called by muse, mutect2, varscan2
- LTBP2 | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV56211488; called by muse, mutect2, varscan2
- LTK | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs771020055, COSV53028700; called by muse, mutect2, varscan2
- LUZP4 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV64219446; called by muse, mutect2
- MAPK11 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57997660, COSV57998415; called by muse, varscan2
- MARK1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs923160469, COSV65069813; called by muse, mutect2, varscan2
- MARK2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1225368156, COSV59286509; called by muse, mutect2
- MAS1 | c.70T>A p.S24T | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV53121834; called by muse, mutect2, varscan2
- MBD3L1 | c.12T>A p.S4R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59776236; called by muse, mutect2, varscan2
- MCF2L2 | c.2002T>G p.F668V | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as rs751613772, COSV61058263; called by muse, mutect2
- MCM6 | c.1221-1G>T p.X407_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as COSV51468165; called by muse, mutect2, varscan2
- MMP20 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 28/818 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs1470699464, COSV52777109; called by muse, mutect2
- MROH2B | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 58/119 reads (49%) | catalogued as rs1201772851, COSV68185301, COSV68187253; called by muse, mutect2, varscan2
- MYH6 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV62452902; called by muse, mutect2, varscan2
- MYH9 | c.1779T>G p.N593K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53390576; called by muse, mutect2, varscan2
- NAP1L2 | c.748A>T p.N250Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65172820; called by muse, mutect2, varscan2
- NAV2 | c.603C>G p.H201Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs371613686, COSV62329223; called by muse, mutect2, varscan2
- NBEA | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59778904; called by muse, varscan2
- NBEAL2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1328424248, COSV52761269; called by muse, mutect2, varscan2
- NCF2 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 147/545 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV62315403, COSV62316275; called by muse, mutect2, varscan2
- NELL2 | c.2207G>T p.C736F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61581079; called by muse, mutect2, varscan2
- NKAP | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1368024930, COSV65056659; called by muse, mutect2, varscan2
- NLRP14 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs369413951, COSV55068540; called by muse, mutect2, varscan2
- NLRP7 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052522, COSV60178449; called by muse, mutect2, varscan2
- NOTCH1 | c.1282A>T p.K428* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV53074401; called by muse, mutect2, varscan2
- NRROS | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV60746955; called by muse, mutect2, varscan2
- NRROS | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV60746966; called by muse, mutect2, varscan2
- NRXN1 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58442928; called by muse, mutect2, varscan2
- NUDT9 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56197467; called by muse, mutect2, varscan2
- NUP98 | c.4244A>C p.Q1415P (on ENST00000359171 / NM_001365126.1; = p.Q1398P on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.106); catalogued as COSV61435952; called by muse, mutect2, varscan2
- OR11H12 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs751621853, COSV101612496; called by muse, mutect2
- OR11H4 | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59559874, COSV59560660; called by muse, mutect2, varscan2
- OR12D3 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.973); catalogued as COSV65829328; called by muse, mutect2, varscan2
- OR51B2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV60916055, COSV60917267; called by muse, mutect2, varscan2
- OR51B2 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 38/156 reads (24%) | catalogued as rs949105971, COSV60917099, COSV60917276; called by muse, mutect2, varscan2
- OR52M1 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64172389; called by muse, mutect2, varscan2
- OR56A1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57363356; called by muse, mutect2, varscan2
- OR5D14 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs774661407, COSV59455667, COSV59456508, COSV59457570; called by muse, mutect2, varscan2
- OR5H6 | c.220C>T p.P74S (on ENST00000642105; = p.P58S on NM_001005479.2) | Missense Mutation (SNP) | VAF 79/497 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV101051831, COSV67351873; called by muse, mutect2, varscan2
- PARP9 | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV64451375; called by muse, mutect2, varscan2
- PCDH15 | c.3012G>A p.L1004= | Splice Region (SNP) | VAF 8/96 reads (8%) | catalogued as COSV57358374; called by muse, mutect2
- PCDHA8 | c.2092G>C p.V698L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as COSV100968966, COSV65329923; called by muse, mutect2, varscan2
- PCDHB10 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs1358381709, COSV53381710; called by muse, mutect2, varscan2
- PCDHGA1 | c.1349del p.P450Qfs*25 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | catalogued as rs1561472048; called by mutect2, pindel, varscan2
- PCDHGA4 | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); catalogued as COSV53995450; called by muse, mutect2, varscan2
- PDZD2 | c.3120C>A p.D1040E | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56866578; called by muse, mutect2, varscan2
- PITPNA | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs192122018, COSV57935386; called by muse, mutect2, varscan2
- PIWIL1 | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV55349831; called by muse, mutect2, varscan2
- PKHD1L1 | c.3883C>A p.L1295I | Missense Mutation (SNP) | VAF 137/297 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs915964728, COSV65748582; called by muse, mutect2, varscan2
- PLA2G4F | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51828438; called by muse, mutect2, varscan2
- PNLIP | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981593, COSV65040597, COSV65041391; called by muse, mutect2, varscan2
- POLN | c.1811C>A p.T604K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs376518009, COSV67026602; called by muse, mutect2, varscan2
- POLQ | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51757527; called by muse, mutect2, varscan2
- PPARGC1A | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV53531321; called by muse, mutect2, varscan2
- PPIAL4G | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV101344007; called by muse, mutect2, varscan2
- PPIG | c.290-2A>G p.X97_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | catalogued as COSV53644788; called by muse, mutect2, varscan2
- PPP2R1A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs945560047, COSV59046753; called by muse, mutect2, varscan2
- PPP4R3B | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs147118353, COSV55407501; called by muse, mutect2, varscan2
- PRG4 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs563970834, COSV63354987; called by muse, mutect2, varscan2
- PROSER1 | c.644-2A>T p.X215_splice | Splice Site (SNP) | VAF 47/169 reads (28%) | catalogued as rs750288022, COSV61488834; called by muse, mutect2, varscan2
- PTH2R | c.1340G>T p.R447I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs1473970625, COSV55915814, COSV99782676; called by muse, mutect2, varscan2
- PTPRR | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51740641; called by muse, mutect2, varscan2
- RANBP10 | c.887A>C p.Q296P | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58159895; called by muse, mutect2, varscan2
- RANBP17 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1173206098, COSV66654089; called by muse, mutect2, varscan2
- RAPGEF4 | c.2362T>C p.F788L | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV51405088; called by muse, mutect2, varscan2
- RFX6 | c.1225A>T p.M409L | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV60587447; called by muse, varscan2
- RNF111 | c.881-1G>A p.X294_splice | Splice Site (SNP) | VAF 38/233 reads (16%) | catalogued as COSV62088401; called by muse, mutect2, varscan2
- RNF144A | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57984171; called by muse, mutect2, varscan2
- RYR3 | c.3011C>A p.T1004N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66801932; called by muse, mutect2, varscan2
- SCN5A | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV60067743; called by muse, mutect2, varscan2
- SCNN1G | c.1053G>C p.M351I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV55600653; called by muse, mutect2, varscan2
- SEC23IP | c.1640A>T p.Y547F | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64832398; called by muse, mutect2, varscan2
- SELP | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.69); catalogued as COSV55255511, COSV55255918; called by muse, mutect2, varscan2
- SEMA4B | c.2282G>T p.C761F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV60174448, COSV60175015; called by muse, mutect2, varscan2
- SH2D1A | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63579395, COSV63579519; called by muse, mutect2, varscan2
- SH3GL2 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV66052896; called by muse, mutect2, varscan2
- SLC15A4 | c.1398C>G p.I466M | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV57162786; called by muse, mutect2, varscan2
- SLC22A9 | c.917G>C p.S306T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1801518, COSV54168860; called by muse, mutect2, varscan2
- SLC30A8 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69974044; called by muse, mutect2, varscan2
- SLC5A6 | c.1092C>G p.L364= | Splice Region (SNP) | VAF 5/102 reads (5%) | catalogued as COSV60160573; called by muse, mutect2
- SLCO2A1 | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60487726; called by muse, mutect2
- SLCO4C1 | c.2090C>A p.T697K | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60513673; called by muse, mutect2, varscan2
- SLITRK3 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV53851265, COSV53852342; called by muse, mutect2, varscan2
- SNRPN | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as COSV57599064; called by muse, mutect2, varscan2
- SOS2 | c.1987A>T p.K663* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV53571307; called by muse, mutect2, varscan2
- SPATA2 | c.1315G>C p.G439R | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.277); catalogued as COSV56867610; called by muse, mutect2, varscan2
- SPATS2 | c.1187G>C p.S396T | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV58921458; called by muse, mutect2, varscan2
- SPHKAP | c.4984C>T p.H1662Y (on ENST00000392056 / NM_001142644.2; = p.H1633Y on NM_030623.3) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs764335137, COSV60871265; called by muse, mutect2, varscan2
- SPTA1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 24/139 reads (17%) | catalogued as COSV63757036; called by muse, mutect2, varscan2
- SPTA1 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV63757038; called by muse, mutect2, varscan2
- STK32B | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767165585, COSV51501735; called by muse, mutect2, varscan2
- STK32B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51501741; called by muse, mutect2, varscan2
- STOML3 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV65511398; called by muse, mutect2, varscan2
- SYDE2 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58324633; called by muse, mutect2, varscan2
- SYNE1 | c.6135del p.I2045Mfs*6 (on ENST00000367255 / NM_182961.4; = p.I2052Mfs*6 on NM_033071.3) | Frame Shift Del (DEL) | VAF 33/273 reads (12%) | catalogued as COSV99584265; called by mutect2, pindel, varscan2
- SYT14 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577985547, COSV55053615, COSV55066267; called by muse, mutect2, varscan2
- TAFA1 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV72039962, COSV72041491; called by muse, mutect2, varscan2
- TBC1D14 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.319); catalogued as COSV68986698; called by muse, mutect2, varscan2
- TBC1D24 | c.1201A>C p.K401Q (on ENST00000646147 / NM_001199107.2; = p.K395Q on NM_020705.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV53547733; called by muse, mutect2, varscan2
- TBCK | c.1396G>C p.D466H (on ENST00000273980 / NM_001163436.4; = p.D403H on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56759603; called by muse, mutect2, varscan2
- TEC | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67405702; called by muse, mutect2, varscan2
- TEX13A | c.713C>G p.T238R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61170363; called by muse, mutect2, varscan2
- TGIF2LX | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV52214728; called by muse, mutect2, varscan2
- TGIF2LX | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV52214739; called by muse, mutect2, varscan2
- TIGD3 | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV52890613; called by muse, mutect2, varscan2
- TMEM26 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs756970684, COSV53263483; called by muse, varscan2
- TMEM260 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1170968257, COSV55101404; called by muse, mutect2, varscan2
- TMPRSS11E | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 78/672 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1487467600, COSV59520393; called by muse, mutect2, varscan2
- TNN | c.3059G>C p.G1020A | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); catalogued as COSV53422442, COSV53431472; called by muse, mutect2, varscan2
- TNR | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV54902062; called by muse, mutect2, varscan2
- TNR | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs150401432, COSV54882302; called by muse, mutect2, varscan2
- TOX2 | c.1262A>T p.Q421L (on ENST00000358131 / NM_001098798.2; = p.Q397L on NM_032883.3) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57891590; called by muse, mutect2, varscan2
- TPH2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV61593266; called by muse, mutect2, varscan2
- TRAPPC9 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV66905612; called by muse, mutect2, varscan2
- TRIM33 | c.1364G>C p.G455A | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV61824536; called by muse, mutect2, varscan2
- TRIM51 | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV55269080; called by muse, mutect2, varscan2
- TRIM58 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1438973082, COSV63571526; called by muse, mutect2, varscan2
- TRMT61B | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60258601; called by muse, mutect2, varscan2
- TRPS1 | c.3493G>C p.D1165H (on ENST00000220888 / NM_001330599.2; = p.D1178H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55253560; called by muse, mutect2, varscan2
- TSHZ3 | c.2690A>T p.N897I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53677647; called by muse, mutect2, varscan2
- TSPYL1 | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63994200; called by muse, mutect2, varscan2
- TTC21A | c.473A>T p.D158V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV57187774; called by muse, mutect2, varscan2
- TTF1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57506180; called by muse, mutect2
- TTN | c.86738C>T p.P28913L (on ENST00000591111; = p.P21489L on NM_003319.4) | Missense Mutation (SNP) | VAF 105/343 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV60219117; called by muse, mutect2, varscan2
- TTN | c.5216T>A p.L1739H (on ENST00000591111; = p.L1693H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | PolyPhen probably damaging (0.999); catalogued as COSV60219175; called by muse, mutect2
- TUBA1A | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV55498439; called by muse, mutect2, varscan2
- TUBGCP2 | c.1070G>C p.S357T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); catalogued as COSV53307297, COSV53307345; called by muse, mutect2, varscan2
- TYRO3 | c.2168G>T p.W723L | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485335; called by muse, mutect2
- TYRO3 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485357; called by muse, mutect2
- UBR2 | c.4100G>T p.R1367M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV65751497; called by muse, mutect2, varscan2
- UGGT2 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as COSV65077280; called by muse, mutect2, varscan2
- UGT2B15 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57735772; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV54440432; called by muse, mutect2, varscan2
- USH2A | c.12082G>T p.A4028S | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56405914; called by muse, mutect2, varscan2
- USH2A | c.9168T>G p.Y3056* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as CD115981, COSV56405933; called by muse, mutect2, varscan2
- VPS13D | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs751395719, COSV104419648, COSV62532453; called by muse, mutect2, varscan2
- WDR19 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56468026, COSV99975417; called by muse, mutect2, varscan2
- XDH | c.1428-2A>T p.X476_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | catalogued as COSV65150322; called by muse, mutect2, varscan2
- ZEB2 | c.851G>T p.C284F | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57961947; called by muse, mutect2, varscan2
- ZNF208 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV68110279; called by muse, mutect2, varscan2
- ZNF227 | c.2153G>T p.C718F | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57313136; called by muse, mutect2, varscan2
- ZNF260 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV72951222, COSV72951268; called by muse, mutect2, varscan2
- ZNF331 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53478575; called by muse, mutect2, varscan2
- ZNF436 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV58359047; called by muse, mutect2, varscan2
- ZNF527 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62232977; called by muse, mutect2, varscan2
- ZNF528 | c.124A>T p.R42W | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64620512; called by muse, mutect2, varscan2
- ZNF560 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV56870078; called by muse, mutect2, varscan2
- ZNF599 | c.1454C>G p.A485G | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61396873, COSV61397796; called by muse, mutect2, varscan2
- ZNF615 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65034427; called by muse, mutect2, varscan2
- ZNF804A | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.387); catalogued as COSV56435272, COSV56461319; called by muse, mutect2, varscan2
- ZNF831 | c.4430C>A p.S1477Y | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV64043173; called by muse, mutect2, varscan2
- ZNF99 | c.1275C>G p.C425W | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV68056190; called by muse, mutect2, varscan2
- ALX3 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALX3 | c.393C>A p.S131R | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOBEC1 | c.376del p.Q126Kfs*14 | Frame Shift Del (DEL) | VAF 87/212 reads (41%) | called by mutect2, pindel, varscan2
- EFHB | c.490del p.V164Lfs*16 | Frame Shift Del (DEL) | VAF 59/222 reads (27%) | called by mutect2, pindel*, varscan2
- FCGBP | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FOXP3 | c.1135_1146+7del p.X379_splice | Splice Site (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- HEATR9 | c.1379T>A p.L460* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- IGHV1-2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KDM4C | c.549del p.W183* | Frame Shift Del (DEL) | VAF 42/236 reads (18%) | called by mutect2, pindel, varscan2
- KLF3 | c.106del p.V36Sfs*31 | Frame Shift Del (DEL) | VAF 27/220 reads (12%) | called by mutect2, pindel, varscan2
- OTOGL | c.3269C>G p.T1090S (on ENST00000547103; = p.T1081S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PPIAL4A | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 130/579 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- PTPRN2 | c.1280_1295del p.K427Sfs*84 | Frame Shift Del (DEL) | VAF 41/204 reads (20%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); called by mutect2, varscan2
- SPN | c.460del p.A154Qfs*54 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel, varscan2
- XKR3 | c.1332C>G p.C444W | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.2020del p.Q674Kfs*31 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3216C>G p.P1072= | Silent (SNP) | VAF 98/174 reads (56%) | catalogued as COSV55295175; called by muse, mutect2, varscan2
- ABCA2 | c.591G>T p.T197= (on ENST00000614293; = p.T167= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs759612927, COSV55804269; called by mutect2, varscan2
- ACAD10 | c.2892C>T p.R964= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs766854319, COSV58160396; called by muse, mutect2, varscan2
- ACSM2A | c.96C>A p.S32= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV54581715, COSV54587680; called by muse, mutect2, varscan2
- ACTN2 | c.669G>T p.L223= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV63977077; called by muse, mutect2, varscan2
- ANK1 | c.4677C>G p.T1559= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV55889224; called by muse, mutect2, varscan2
- ANKS1A | c.1242G>T p.P414= | Silent (SNP) | VAF 69/303 reads (23%) | catalogued as rs765405017, COSV100832736, COSV64462746; called by muse, mutect2, varscan2
- ARAP2 | c.1707A>G p.L569= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as rs763786030, COSV58289824; called by muse, mutect2, varscan2
- BCO1 | c.1176A>G p.Q392= | Silent (SNP) | VAF 4/75 reads (5%) | catalogued as COSV50730517; called by muse, mutect2
- C5orf15 | c.300A>T p.A100= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV51548816; called by muse, mutect2, varscan2
- C8A | c.810A>T p.S270= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV63485672; called by muse, mutect2, varscan2
- CACTIN | c.393G>T p.A131= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- CCDC14 | c.2364A>T p.V788= (on ENST00000488653; = p.V740= on NM_022757.5) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV59946517; called by muse, mutect2, varscan2
- CD5L | c.570C>T p.R190= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV63822670; called by muse, mutect2, varscan2
- CHST8 | c.609C>A p.S203= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as COSV52861307; called by muse, mutect2, varscan2
- CNTNAP5 | c.1101C>A p.P367= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV70499855, COSV70509030; called by muse, mutect2
- CXCR4 | c.75G>A p.K25= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as COSV54014921; called by muse, mutect2, varscan2
- DCAF4L2 | c.237G>T p.A79= | Silent (SNP) | VAF 56/227 reads (25%) | catalogued as COSV60476744, COSV60480732; called by muse, mutect2, varscan2
- DCAF8L1 | c.1656G>T p.V552= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as COSV71595425; called by muse, mutect2, varscan2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- DNAJC6 | c.1434C>G p.V478= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV54779002; called by muse, mutect2, varscan2
- DOCK2 | c.4563C>A p.T1521= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV56974876; called by muse, mutect2, varscan2
- DPEP3 | c.622C>T p.L208= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1409295298, COSV52052160; called by muse, mutect2, varscan2
- EMILIN3 | c.1441C>T p.L481= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as rs1215911140, COSV60037644; called by muse, mutect2, varscan2
- EVC2 | c.2616G>T p.R872= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV60398622; called by muse, mutect2, varscan2
- FIBIN | c.241C>A p.R81= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV59413268; called by muse, mutect2, varscan2
- FLNB | c.1722C>A p.S574= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV55888127; called by muse, mutect2
- GALNT16 | c.1377C>A p.I459= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV61886988; called by muse, mutect2, varscan2
- GDPD2 | c.696C>A p.A232= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV65533776; called by muse, mutect2, varscan2
- GPR31 | c.99G>T p.A33= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV64761822; called by muse, mutect2, varscan2
- GPX7 | c.453A>T p.P151= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as COSV63652778; called by muse, mutect2, varscan2
- GRB10 | c.1164G>T p.T388= (on ENST00000398812; = p.T342= on NM_001001549.3) | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60008206, COSV60009659; called by muse, mutect2, varscan2
- HNRNPK | c.1353G>C p.L451= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as COSV61090407; called by muse, mutect2, varscan2
- HS3ST4 | c.1200A>T p.P400= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV58824639; called by muse, mutect2, varscan2
- HUWE1 | c.12270C>T p.T4090= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV53356819; called by muse, mutect2, varscan2
- IFI44 | c.585T>C p.I195= | Silent (SNP) | VAF 29/257 reads (11%) | catalogued as COSV66075227; called by muse, mutect2, varscan2
- ISLR2 | c.189C>T p.I63= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV62302876; called by muse, mutect2, varscan2
- ISLR2 | c.507G>T p.A169= | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as COSV62302898; called by muse, varscan2
- KCND2 | c.375C>A p.I125= | Silent (SNP) | VAF 97/341 reads (28%) | catalogued as COSV58578437; called by muse, mutect2, varscan2
- KERA | c.489C>T p.S163= | Silent (SNP) | VAF 54/368 reads (15%) | catalogued as COSV57131361; called by muse, varscan2
- KLHDC10 | c.516G>T p.T172= | Silent (SNP) | VAF 82/226 reads (36%) | catalogued as COSV59050562, COSV59053112; called by muse, mutect2, varscan2
- KRTAP13-3 | c.225C>T p.P75= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV61879887; called by muse, mutect2, varscan2
- LCT | c.3717G>T p.S1239= | Silent (SNP) | VAF 31/223 reads (14%) | catalogued as rs151165674, COSV51554234; called by muse, mutect2, varscan2
- LILRA2 | c.1248G>T p.V416= | Silent (SNP) | VAF 63/220 reads (29%) | catalogued as COSV52193961; called by muse, mutect2, varscan2
- MADD | c.1980G>C p.L660= | Silent (SNP) | VAF 28/221 reads (13%) | catalogued as COSV60627434; called by muse, mutect2, varscan2
- MAGED2 | c.408A>C p.T136= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54498793; called by muse, mutect2, varscan2
- MCRS1 | c.507G>T p.R169= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59460769; called by muse, mutect2, varscan2
- MEGF8 | c.5382G>T p.G1794= (on ENST00000251268 / NM_001271938.2; = p.G1727= on NM_001410.3) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV52094427; called by muse, mutect2, varscan2
- MMP15 | c.1500C>T p.Y500= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV54680718; called by muse, mutect2, varscan2
- MYOM2 | c.1389G>T p.A463= | Silent (SNP) | VAF 74/430 reads (17%) | catalogued as COSV50705177, COSV50743116; called by muse, varscan2
- NCAPG2 | c.3237G>T p.V1079= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV51989935; called by muse, mutect2, varscan2
- NELL2 | c.1218C>T p.N406= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs370216357; called by muse, mutect2, varscan2
- NSD2 | c.1131A>T p.S377= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV56393892; called by muse, mutect2, varscan2
- NSF | c.1104A>C p.L368= | Silent (SNP) | VAF 18/169 reads (11%) | catalogued as COSV56575900; called by muse, mutect2, varscan2
- OCA2 | c.2202G>T p.L734= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV62351330; called by muse, mutect2
- OR13C9 | c.735G>T p.L245= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as COSV52243008; called by muse, mutect2, varscan2
- OR5D18 | c.732C>T p.S244= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as rs866560731, COSV100450775, COSV61738059; called by muse, mutect2, varscan2
- OR5J2 | c.774C>T p.S258= | Silent (SNP) | VAF 83/320 reads (26%) | catalogued as COSV56621842, COSV56621992, COSV56622459; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.480G>A p.R160= (on ENST00000259318 / NM_001136562.3; = p.R391= on NM_007203.5) | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52179490; called by muse, mutect2, varscan2
- PLEKHG4B | c.549C>T p.P183= (on ENST00000283426; = p.P539= on NM_052909.5) | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as COSV52047774, COSV52051807; called by muse, mutect2, varscan2
- PNO1 | c.222A>G p.E74= | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as COSV54562349; called by muse, mutect2, varscan2
- RAB21 | c.453A>T p.A151= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV54229552; called by muse, mutect2, varscan2
- RPTN | c.831A>T p.L277= | Silent (SNP) | VAF 171/782 reads (22%) | catalogued as COSV60168309; called by muse, mutect2, varscan2
- SCLY | c.450G>T p.S150= (on ENST00000651534; = p.S142= on NM_016510.7) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54542983, COSV99616489; called by muse, mutect2, varscan2
- SCN10A | c.219A>G p.E73= | Silent (SNP) | VAF 104/287 reads (36%) | catalogued as COSV71862303; called by muse, mutect2, varscan2
- SELENOO | c.1470G>A p.L490= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV50563564; called by muse, mutect2
- SLC25A28 | c.843A>G p.P281= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV65125595; called by muse, mutect2, varscan2
- SLC27A6 | c.69G>C p.L23= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV52485530; called by muse, mutect2, varscan2
- SLC35D2 | c.351A>T p.L117= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV53563964; called by muse, mutect2, varscan2
- SMAD1 | c.1329C>T p.P443= | Silent (SNP) | VAF 100/302 reads (33%) | catalogued as COSV57472564; called by muse, mutect2, varscan2
- STAG3 | c.1347C>T p.Y449= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100425701, COSV57933201; called by muse, mutect2, varscan2
- SYCP1 | c.189T>C p.D63= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV65699806; called by muse, mutect2, varscan2
- SYNE1 | c.16665A>G p.A5555= (on ENST00000367255 / NM_182961.4; = p.A5484= on NM_033071.3) | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs1042078718, COSV55047361; called by muse, mutect2, varscan2
- TGM6 | c.1543C>T p.L515= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs371303959, COSV52482523; called by muse, mutect2, varscan2
- THBS2 | c.414C>T p.S138= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs1405909235, COSV64681000; called by muse, mutect2, varscan2
- TMC5 | c.1404C>T p.F468= (on ENST00000396229 / NM_001105248.1; = p.F222= on NM_024780.5) | Silent (SNP) | VAF 8/151 reads (5%) | catalogued as COSV54906685, COSV54907341; called by muse, mutect2
- TMCC1 | c.1119C>T p.A373= (on ENST00000393238 / NM_001349268.2; = p.A49= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs115654568, COSV61441942; called by muse, mutect2, varscan2
- TMF1 | c.3204A>G p.E1068= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV68375290; called by muse, mutect2, varscan2
- UBE2NL | c.381G>A p.V127= | Silent (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- VAMP7 | c.297A>G p.P99= | Silent (SNP) | VAF 65/226 reads (29%) | catalogued as COSV52902443; called by muse, mutect2, varscan2
- VDR | c.1050G>A p.A350= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as rs4987032; called by muse, mutect2
- VPS45 | c.303G>C p.V101= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV64888521; called by muse, mutect2, varscan2
- ZNF384 | c.1716G>A p.E572= (on ENST00000361959; = p.E511= on NM_133476.5) | Silent (SNP) | VAF 52/513 reads (10%) | catalogued as COSV58555880; called by muse, mutect2, varscan2
- ZSCAN2 | c.1053G>A p.T351= | Silent (SNP) | VAF 58/302 reads (19%) | catalogued as rs1434448229, COSV57571957; called by muse, mutect2, varscan2
- C3P1 | n.2321A>T | RNA (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- CFAP74 | c.4654-224T>A | Intron (SNP) | VAF 18/82 reads (22%) | catalogued as COSV60587572; called by muse, mutect2, varscan2
- EI24P4 | n.1019G>T | RNA (SNP) | VAF 56/365 reads (15%) | catalogued as rs765034927; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16883C>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- LIN9 | c.244+456G>C | Intron (SNP) | VAF 28/106 reads (26%) | catalogued as rs764076330, COSV60246182; called by muse, varscan2
- NDUFAF5 | c.-2A>T | 5'UTR (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99176377; called by muse, mutect2
- SSPOP | n.7447C>A | RNA (SNP) | VAF 25/69 reads (36%) | catalogued as COSV50488576; called by muse, mutect2, varscan2
